Gene-level copy-number profile of tumor specimen TCGA-VQ-A94T-01A from TCGA case TCGA-VQ-A94T, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.1 years (26,702 days).
Specimen TCGA-VQ-A94T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2b34de68-adec-42c4-9641-e9a208bde74d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A94T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44b352d2-5dbb-401a-adbb-4f357c7b39b0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 11; copy number 2: 16,631; copy number 3: 24,233; copy number 4: 13,565; copy number 5: 4,275; copy number 6: 900; copy number 7: 69; copy number 42: 6; copy number 48: 16; copy number 51: 5; copy number 52: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A94T-01A-11D-A40Z-01): tumor purity 0.75, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,777,357–13,034,326, 18 genes (within-gene range 0–2): AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1.
- chr9:22,646,200–29,318,952, 59 genes: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr9:32,293,558–32,573,184, 8 genes: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 119 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:13,710,531–14,400,963, 1 gene, copy number 52 (within-gene range 3–52): LINC00276.
- chr2:14,274,622–17,123,140, 38 genes, copy number 48–52: RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168.
- chr2:18,547,386–18,589,572, 5 genes, copy number 51: AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P.
- chr2:20,155,618–20,246,387, 6 genes, copy number 42: RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr9:6,007,826–7,175,648, 26 genes, copy number 7 (within-gene range 2–7): MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1.
- chr9:35,657,751–36,304,924, 43 genes, copy number 7: RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
